Somatic mutation profile of tumor specimen MP2PRT-PATVXM-TMP1-A (aliquot MP2PRT-PATVXM-TMP1-A-1-0-D-A80K-36) from MP2PRT case MP2PRT-PATVXM, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.2 years (2,280 days).
Specimen MP2PRT-PATVXM-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9243fb0e-ba08-4ef0-9d75-bea4b8abac1f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATVXM-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATVXM-NB1-A-1-0-D-A80K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3d02e0c5-9bd7-4c39-829b-7d50785cf892

The open-access MAF lists 17 somatic variants for this specimen: 11 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 5, In Frame Ins 1, Splice Site 1, Frame Shift Del 1, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID3C | c.187C>T p.R63W | Missense Mutation (SNP) | VAF 39/832 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs375833800; called by muse, mutect2
- NAV2 | c.1486C>T p.R496W (on ENST00000396087 / NM_001244963.2; = p.R473W on NM_145117.5) | Missense Mutation (SNP) | VAF 238/594 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs759031123, COSV62331129; called by muse, varscan2
- OR52E8 | c.629C>T p.S210F | Missense Mutation (SNP) | VAF 165/404 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.049); catalogued as COSV66205815, COSV66205972, COSV66209543; called by muse, mutect2, varscan2
- PCDHB2 | c.25C>T p.R9C | Missense Mutation (SNP) | VAF 30/336 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV52030175; called by muse, mutect2
- PCDHGB4 | c.688G>A p.V230I | Missense Mutation (SNP) | VAF 19/620 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as COSV53942996; called by muse, mutect2
- ST18 | c.1864C>G p.R622G | Missense Mutation (SNP) | VAF 241/550 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV52485545, COSV52501022, COSV52509349; called by muse, mutect2, varscan2
- GIGYF2 | c.2826_2828delinsTCAGGG p.T943delinsQG | In Frame Ins (INS) | VAF 42/475 reads (9%) | called by pindel, varscan2*
- IGHV4-39 | chr14:106421705 TGTGTGTCTCGCACAGTAATACA>CAT | Missense Mutation (DEL) | VAF 126/136 reads (93%) | called by pindel, varscan2*
- METTL15 | c.600-8_604del p.X200_splice | Splice Site (DEL) | VAF 106/281 reads (38%) | called by mutect2, pindel, varscan2
- METTL2A | c.91_92insGGGCCAG p.V31Gfs*41 | Frame Shift Ins (INS) | VAF 48/528 reads (9%) | called by mutect2, pindel
- TAS2R43 | c.885del p.W295Cfs*3 | Frame Shift Del (DEL) | VAF 211/527 reads (40%) | called by mutect2, pindel, varscan2
- GPR173 | c.114G>A p.A38= | Silent (SNP) | VAF 40/602 reads (7%) | catalogued as rs782503467; called by muse, mutect2
- NOC2L | c.1779C>T p.F593= | Silent (SNP) | VAF 32/420 reads (8%) | catalogued as rs772911099, COSV58985864; called by muse, mutect2
- PRDM11 | c.1344T>C p.C448= (on ENST00000530656 / NM_001359633.1; = p.C414= on NM_001256695.1) | Silent (SNP) | VAF 227/603 reads (38%) | catalogued as rs140030684; called by muse, mutect2, varscan2
- SHANK2 | c.2463C>T p.I821= | Silent (SNP) | VAF 194/384 reads (51%) | catalogued as rs141118155; called by muse, mutect2, varscan2
- XRRA1 | c.2313C>T p.F771= | Silent (SNP) | VAF 308/605 reads (51%) | catalogued as rs762369425, COSV55134230; called by muse, mutect2, varscan2
- HYDIN | c.2075+34G>A | Intron (SNP) | VAF 225/487 reads (46%) | catalogued as rs371599741; called by muse, mutect2, varscan2
